Gene-level copy-number profile of tumor specimen TCGA-3N-A9WD-06A from TCGA case TCGA-3N-A9WD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.1 years (30,346 days).
Specimen TCGA-3N-A9WD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6568e893-a9dd-4299-8132-b2c04ef95b46.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3N-A9WD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64e99c73-8a29-4d10-ae87-94b39209611d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 13,174; copy number 2: 41,242; copy number 3: 5,330; copy number 4: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3N-A9WD-06A-11D-A38F-01): tumor purity 0.45, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
